TCGA case TCGA-F4-6461 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2900eadd-7e27-4371-94e5-7d58cdff0138

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 41 years; Vital status: Dead; Days to death: 338 days.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Hepatic flexure of colon; Classification of tumor: primary; Age at diagnosis: 41.5 years (15,151 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T4b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 5; Lymph nodes tested: 5; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 42.3 years (15,439 days); Days to diagnosis: 288 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: Tumor Free.
- Day 288 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 288 days.
- Days to follow up: 338 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 57 kg; Height: 151 cm; BMI: 25.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-F4-6461-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.8; Intermediate dimension: 2.2; Shortest dimension: 0.5.
  Slide TCGA-F4-6461-01A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide TCGA-F4-6461-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 7; Percent necrosis: 3; Percent stromal cells: 20; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-F4-6461-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-F4-6461-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Hepatic Flexure; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 338 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 338 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 288 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-F4-6461-01A-11D-1770-01): tumor purity 0.59, ploidy 1.94, whole-genome doublings 0.
